Somatic mutation profile of tumor specimen TCGA-ET-A4KN-01A (aliquot TCGA-ET-A4KN-01A-11D-A257-08) from TCGA case TCGA-ET-A4KN, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 51.7 years (18,889 days).
Specimen TCGA-ET-A4KN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fbc4e13-aa8a-44cc-81e7-c8046526f869.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A4KN-10A (Blood Derived Normal), aliquot TCGA-ET-A4KN-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/056295fc-904b-4c53-a0d6-5398420584a6

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52455346; called by muse, mutect2
- BOD1L1 | c.8087G>A p.G2696E | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV50006881, COSV50088138; called by muse, mutect2, varscan2
- CDKN1A | c.26G>C p.R9P | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV55187157; called by muse, mutect2, varscan2
- GLI2 | c.1084G>A p.V362I | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as rs370677655; called by muse, mutect2, varscan2
- ITGA7 | c.1442A>C p.K481T (on ENST00000555728; = p.K437T on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV57692048; called by muse, mutect2
- MED11 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.049); catalogued as rs1190771104, COSV53411132; called by muse, mutect2, varscan2
- MMP2 | c.257C>G p.T86R | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54599174; called by muse, mutect2, varscan2
- PTK2B | c.1108G>A p.G370S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV57750269; called by muse, mutect2, varscan2
- CASZ1 | c.2386C>T p.P796S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.085); called by muse, mutect2
- MON2 | c.5046C>T p.C1682= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs753579524, COSV54803510; called by muse, mutect2, varscan2
